Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3372, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3372-01A (Primary Tumor).

[page 1 of 2]
Collected Date & Time

Result Name	Results	Units	Reference Range
☒ Surgical Pathology	COPY TO:		

COPY TO:

IO Consultation

"Grossly consistent with renal cell carcinoma, no FS"

Pre-Op Diagnosis

Left renal mass

Post-Op Diagnosis

Same as above

Clinical History

Nothing indicated

Gross Description:

Received in a single container labeled [REDACTED] - left kidney" is a 1190 gram previously partially sectioned left nephrectomy specimen surrounded by a large amount of perinephric adipose tissue and faced anteriorly by a moderate amount of Gerota's fascia. The specimen, on reconstruction, as received measures 28.8 x 14.6 x 10.0 cm. The margins of resection include 2.1 cm of grossly patent renal artery and 2.6 cm of grossly patent renal vein with multiple staple lines and plastic surgical clips in place. In addition, there is 9.6 cm of grossly patent ureter. Within the superior medial aspect of the adipose tissue is a 7.1 x 2.6 x 1.5 cm grossly unremarkable recognizable adrenal gland. The capsule strips with slight difficulty to reveal an organ measuring overall 12.7 x 8.0 x 7.8 cm. There is a lobulated smooth tan-brown cortex. Much of the lateral aspect of the lower pole extending into the central portion is occupied by a 6.9 x 5.5 x 5.3 cm well-defined thinly encapsulated gray-tan to yellow lesion with a markedly hyalinized cut surface showing marginal areas of lobulated yellow fleshy tissue. In addition, there are several areas of hemorrhage. This lesion extends beyond the plane of the renal parenchyma into the surrounding adipose tissue where it is seen at its nearest point within 0.2 cm of the fatty margin. In one area the lesion grossly appears to break through the capsule into the surrounding adipose tissue; however, this appears as a single lobulation measuring 1.5 cm in greatest dimension. The specimen is received after operative consult, which is reported as "grossly consistent with renal cell carcinoma, no FS" by Dr. [REDACTED]. The remaining renal parenchyma is compressed by the lesion with a few vascular structures markedly compressed in the area of the capsule. The cortex is up to 0.6 cm and homogeneous tan-brown. The corticomedullary junction is well defined. The medulla is slightly hyalinized tan-gray to brown. The calyces and pelvis are lined by smooth tan-white mucosa extending into the ureter. Representative sections are submitted labeled as follows: A - vascular and ureteral margins; B-G - lesion and surrounding tissue; H - random uninvolved parenchyma; I - adrenal gland. Also received in the same container are three tissue cassettes each labeled [REDACTED]

[page 2 of 2]
Microscopic Description:

Slides are reviewed labeled [REDACTED]

Final Diagnosis

Left kidney:

Renal cell carcinoma, clear cell type.

Tumor site: Neoplasm is noted in the lateral aspect of the lower pole extending into the central portion of the kidney.

Tumor size: 6.9 x 5.5 x 5.3 cm.

Macroscopic extent of tumor: Neoplasm appears to be primarily limited to the kidney though a microscopic focus of neoplasm is present in the perinephric adipose tissue.

Nuclear grade: Fuhrman grade 2/4.

Lymphovascular space invasion: No.

Transcapsular invasion: Yes.

Renal vein invasion: No.

Vena caval invasion: Not resected.

Adrenal gland: Benign adrenal gland tissue without evidence of metastatic disease.

Surgical margin status:

Soft tissue margins: Negative.

Ureteral margin: Negative.

Vascular margins: Negative.

Other:

Chronic pyelonephritis.

Intra-operative consultation above confirmed on permanent sections.

Stage: pT3NXMX. PAS 9 SPC-A

CPT: 88307 x 2, 88329

Comments

The pathologic staging T3 is based on the presence of a 1.5 cm lobule of neoplasm in the perinephric adipose tissue.

This test has been finalized at the [REDACTED] Campus.

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 7fe7400c-673b-4e00-8e1f-93f5b0386e54 (TCGA-A3-3372.1727C5C1-C8AF-49AE-8F93-448BB9AE9303.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).